Somatic mutation profile of tumor specimen 0DYC3N from CCDI case PBCSNY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.6 years (956 days).
Specimen 0DYC3N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5909bbb8-baae-452a-9b0d-941837c2c16d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYC3F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da479b0-6922-42bd-a846-0659862aaf22

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUMA1 | c.3001C>T p.Q1001* | Nonsense Mutation (SNP) | VAF 116/296 reads (39%) | catalogued as COSV61183675; called by muse, varscan2
- BCL11B | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.246); called by muse, varscan2
- LCE1A | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 26/958 reads (3%) | called by muse, mutect2
- TFR2 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 151/507 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
